Somatic mutation profile of tumor specimen MP2PRT-PASJBX-TMP1-A (aliquot MP2PRT-PASJBX-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASJBX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,369 days).
Specimen MP2PRT-PASJBX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b90a752-14ff-4552-a3b5-f66dda551540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJBX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJBX-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1c5f84b-8fd3-492a-b201-39b3a7d765e8

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 4, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IQSEC3 | c.2167G>A p.E723K (on ENST00000538872 / NM_001170738.2; = p.E420K on NM_015232.1) | Missense Mutation (SNP) | VAF 184/474 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1555094507; called by muse, mutect2, varscan2
- KCNK13 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 63/567 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs747259528; called by muse, mutect2, varscan2
- SETD2 | c.2753C>A p.S918* | Nonsense Mutation (SNP) | VAF 48/178 reads (27%) | catalogued as COSV57450237; called by muse, mutect2, varscan2
- TRPM4 | c.2208C>T p.V736= | Splice Region (SNP) | VAF 137/301 reads (46%) | catalogued as rs139307985; ClinVar: likely benign; called by muse, mutect2, varscan2
- LZTR1 | c.2411_2412insGGGGC p.K805Gfs*10 | Frame Shift Ins (INS) | VAF 65/297 reads (22%) | called by mutect2, pindel, varscan2
- TRIM67 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 312/931 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZFHX4 | c.5182G>T p.A1728S | Missense Mutation (SNP) | VAF 39/463 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2
- ACTG1 | c.1074C>T p.S358= | Silent (SNP) | VAF 214/572 reads (37%) | catalogued as rs1555666367; called by muse, mutect2
- COBL | c.1884G>A p.A628= | Silent (SNP) | VAF 44/397 reads (11%) | catalogued as rs376323100; called by muse, mutect2, varscan2
- CSGALNACT1 | c.303C>T p.S101= | Silent (SNP) | VAF 237/585 reads (41%) | catalogued as rs540351043; called by muse, mutect2, varscan2
- ELMO1 | c.1173C>T p.H391= | Silent (SNP) | VAF 33/377 reads (9%) | called by muse, mutect2
- PCNT | c.3573G>C p.L1191= | Silent (SNP) | VAF 140/528 reads (27%) | called by muse, mutect2, varscan2
